Somatic mutation profile of tumor specimen TCGA-CV-7235-01A (aliquot TCGA-CV-7235-01A-11D-2012-08) from TCGA case TCGA-CV-7235, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 67.9 years (24,800 days).
Specimen TCGA-CV-7235-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d2ad328-a4fa-4977-b742-255f092d37f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7235-10A (Blood Derived Normal), aliquot TCGA-CV-7235-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2669607c-d1c3-41c2-89f1-84c0465b9101

The open-access MAF lists 140 somatic variants for this specimen: 103 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 35, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, Intron 2, Splice Region 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 46/73 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC098582.1 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99985933, COSV99986017; called by muse, mutect2
- ADAMTS9 | c.1009A>C p.I337L | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99900181; called by muse, mutect2, varscan2
- ADCY2 | c.1965C>A p.S655R | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100604086; called by muse, mutect2, varscan2
- AHNAK2 | c.6447A>T p.K2149N | Missense Mutation (SNP) | VAF 215/890 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100318904; called by muse, varscan2
- ANKH | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99415858; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4396G>T p.E1466* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99784422; called by muse, mutect2, varscan2
- ANKRD26 | c.4664A>G p.Y1555C | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs774254518, COSV101063398; called by muse, mutect2, varscan2
- APOB | c.13659G>C p.K4553N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99267979; called by muse, mutect2, varscan2
- ARHGEF7 | c.2432A>G p.Y811C (on ENST00000646102 / NM_001354046.1; = p.Y595C on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs750883104, COSV99522113; called by muse, mutect2, varscan2
- ATXN2 | c.2576C>T p.P859L (on ENST00000550104; = p.P699L on NM_002973.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs766655295, COSV101112904; called by muse, mutect2, varscan2
- BCL9L | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 95/187 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs147951163; called by muse, mutect2, varscan2
- BRPF3 | c.1715G>A p.R572K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100326178; called by muse, mutect2, varscan2
- BTN1A1 | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99764553; called by muse, mutect2, varscan2
- CACNG2 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100269066; called by muse, varscan2
- CALM3 | c.154A>G p.M52V | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); catalogued as COSV99355325; called by muse, mutect2, varscan2
- CCP110 | c.2704-2A>G p.X902_splice | Splice Site (SNP) | VAF 27/82 reads (33%) | catalogued as COSV101195345; called by muse, mutect2, varscan2
- CEP41 | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs782780788, COSV99782932; called by muse, mutect2, varscan2
- CLEC4E | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100222750, COSV55226871; called by muse, mutect2, varscan2
- CMTM8 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs752120687, COSV100282581; called by muse, mutect2, varscan2
- COCH | c.374C>G p.S125C (on ENST00000216361 / NM_001347720.1; = p.S60C on NM_004086.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV99363918; called by muse, mutect2, varscan2
- COL27A1 | c.3718G>C p.G1240R | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621317; called by muse, mutect2, varscan2
- CPAMD8 | c.1888_1890del p.F630del (on ENST00000651564; = p.F583del on NM_015692.5) | In Frame Del (DEL) | VAF 20/120 reads (17%) | catalogued as rs747532333; called by pindel, varscan2
- CPAMD8 | c.595G>A p.V199I (on ENST00000651564; = p.V152I on NM_015692.5) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as rs533642927, COSV99359064; called by muse, mutect2, varscan2
- CSMD3 | c.3832G>C p.G1278R (on ENST00000297405 / NM_001363185.1; = p.G1174R on NM_052900.3) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52165357, COSV99847243; called by muse, mutect2, varscan2
- CSNK1D | c.339C>T p.I113= | Splice Region (SNP) | VAF 56/97 reads (58%) | catalogued as COSV99484752; called by muse, mutect2, varscan2
- CYP2W1 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.829); catalogued as rs763439785, COSV58271987; called by muse, mutect2, varscan2
- DMBT1 | c.7375G>A p.G2459R (on ENST00000338354 / NM_001377530.1; = p.G1702R on NM_004406.3) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs777578701, COSV57554139; called by muse, mutect2, varscan2
- DSC1 | c.2086G>T p.A696S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV99938268; called by muse, mutect2, varscan2
- DSP | c.7576A>G p.S2526G | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV101131754; called by muse, mutect2, varscan2
- ELP4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199901084, COSV63356131; called by muse, mutect2, varscan2
- EYA1 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100380259; called by muse, mutect2, varscan2
- FAM47A | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100650064; called by muse, mutect2, varscan2
- FLOT1 | c.952-1G>C p.X318_splice | Splice Site (SNP) | VAF 44/231 reads (19%) | catalogued as COSV100899811; called by muse, mutect2, varscan2
- FOXJ3 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.954); catalogued as COSV100692215; called by muse, mutect2, varscan2
- GCC2 | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100565642; called by muse, mutect2, varscan2
- GCNT2 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101097635; called by muse, mutect2, varscan2
- GNPTAB | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100172389, COSV68449822; called by muse, mutect2, varscan2
- GON4L | c.2200C>T p.Q734* | Nonsense Mutation (SNP) | VAF 21/177 reads (12%) | catalogued as COSV99675718; called by muse, mutect2, varscan2
- GRM4 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs748586184, COSV65211417; called by muse, mutect2, varscan2
- GTDC1 | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as COSV99601810; called by muse, mutect2, varscan2
- KDM5B | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99351390; called by muse, mutect2, varscan2
- LIG4 | c.958A>C p.K320Q | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV100800061, COSV63596664; called by muse, mutect2, varscan2
- LIPC | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.091); catalogued as COSV100134858; called by muse, mutect2, varscan2
- LRP1 | c.2890C>G p.R964G | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.998); catalogued as COSV54517694, COSV99677178; called by muse, mutect2, varscan2
- LRP10 | c.2059G>C p.D687H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100612497; called by muse, mutect2, varscan2
- MANSC1 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1298054441, COSV101115915; called by muse, mutect2, varscan2
- MAP4K2 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV99581690; called by muse, mutect2, varscan2
- MCU | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749854641, COSV100849267; called by muse, mutect2, varscan2
- MSX2 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99496979; called by muse, mutect2, varscan2
- MYH8 | c.3684G>T p.K1228N | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV101238536; called by muse, mutect2, varscan2
- NABP1 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755199528, COSV100323102; called by muse, mutect2, varscan2
- NFE2L3 | c.1861_1862del p.K621Efs*7 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | catalogued as rs777869574, COSV50227502; called by mutect2, pindel, varscan2
- NRG3 | c.1047A>T p.E349D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV100932547; called by muse, mutect2, varscan2
- NXF1 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs781740092, COSV99586301; called by muse, mutect2, varscan2
- PACS1 | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100270568, COSV57696255; called by muse, mutect2, varscan2
- PCSK2 | c.1648G>C p.D550H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV99360683; called by muse, mutect2, varscan2
- PDE5A | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53353754; called by muse, mutect2, varscan2
- PFKM | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV100402728; called by muse, mutect2
- PGBD1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as COSV52554786; called by muse, mutect2, varscan2
- PHF10 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1291125002, COSV100200113; called by muse, mutect2, varscan2
- PLEKHG4B | c.322T>C p.S108P (on ENST00000283426; = p.S464P on NM_052909.5) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99361033; called by muse, mutect2
- PRDX2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as COSV100040343; called by muse, varscan2
- PSMB2 | c.536G>C p.S179T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100951610; called by muse, mutect2, varscan2
- PUS1 | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1379048326, COSV100435288; called by muse, mutect2, varscan2
- RER1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.915); catalogued as rs746542852, COSV100088011; called by muse, mutect2, varscan2
- RIF1 | c.872A>C p.K291T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99691229; called by muse, mutect2
- RORB | c.1147C>A p.R383= (on ENST00000396204 / NM_001365023.1; = p.R372= on NM_006914.4) | Splice Region (SNP) | VAF 26/47 reads (55%) | catalogued as COSV100974438, COSV65338270; called by muse, mutect2, varscan2
- ROS1 | c.5839C>G p.L1947V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100877694; called by muse, mutect2, varscan2
- RYR2 | c.14228T>C p.L4743P | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100772846; called by muse, mutect2, varscan2
- SCN1A | c.2619G>T p.W873C (on ENST00000303395 / NM_001202435.3; = p.W862C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100322051; called by muse, mutect2, varscan2
- SCRIB | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs761006834, COSV100254118; called by muse, mutect2, varscan2
- SEMA5A | c.2213C>A p.A738D | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV101228713; called by muse, mutect2, varscan2
- SEMA6D | c.1862C>G p.S621C | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as COSV100317596; called by muse, mutect2, varscan2
- SHANK2 | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99576016; called by muse, mutect2
- SMTN | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100294904; called by muse, mutect2, varscan2
- SON | c.5207C>T p.P1736L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs752554467, COSV99279757; called by muse, mutect2, varscan2
- SPATS2L | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as COSV100660875, COSV62352109; called by muse, mutect2, varscan2
- STAT1 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV100700022; called by muse, mutect2
- STOML1 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99167898; called by muse, mutect2
- STYXL2 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs748255310, COSV54801982; called by mutect2, varscan2
- SV2A | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100975267; called by muse, mutect2, varscan2
- TANC1 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as rs753195213, COSV55084852, COSV99715172; called by muse, mutect2, varscan2
- TEX15 | c.7292A>C p.N2431T (on ENST00000256246; = p.N2814T on NM_001350162.2) | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV99822099; called by muse, mutect2, varscan2
- TTN | c.31255G>C p.E10419Q (on ENST00000591111; = p.E9492Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/224 reads (9%) | PolyPhen probably damaging (0.969); catalogued as COSV100629364; called by muse, mutect2
- UBN1 | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99278613; called by muse, mutect2, varscan2
- UCHL5 | c.974C>G p.A325G | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100815501; called by muse, mutect2
- UNC5C | c.1401C>G p.N467K | Missense Mutation (SNP) | VAF 61/341 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV101498030; called by muse, mutect2, varscan2
- VIRMA | c.2022-1G>C p.X674_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99889449; called by muse, mutect2, varscan2
- VPS13A | c.3938A>G p.N1313S | Missense Mutation (SNP) | VAF 82/122 reads (67%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100653505; called by muse, mutect2, varscan2
- WWP1 | c.1883A>G p.Y628C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55358591; called by muse, mutect2, varscan2
- ZAN | c.4070G>C p.R1357P | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100770314; called by muse, mutect2, varscan2
- ZNF181 | c.1412G>T p.S471I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV101106454; called by muse, mutect2, varscan2
- ZNF322 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101338502; called by muse, mutect2, varscan2
- ZNF655 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV53159830; called by muse, mutect2, varscan2
- ZNF8 | c.968G>T p.C323F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV99544546; called by muse, mutect2, varscan2
- ZSWIM8 | c.2524A>C p.T842P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV101290135; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1166A>G p.N389S | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.63); PolyPhen benign (0); called by mutect2, varscan2
- FAM13B | c.1317_1321del p.D439Efs*5 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- IGHV1OR15-9 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- IGKV3D-7 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- RADX | c.876del p.G293Vfs*2 | Frame Shift Del (DEL) | VAF 42/96 reads (44%) | called by mutect2, pindel, varscan2
- TGFBI | c.1118_1119del p.P373Rfs*8 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel
- AC004922.1 | c.1110C>T p.S370= | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as rs144704984; called by muse, mutect2, varscan2
- AC098582.1 | c.1242C>T p.L414= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99986016; called by muse, mutect2
- ANK2 | c.117C>A p.A39= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV52180321; called by muse, mutect2, varscan2
- ANKMY1 | c.159C>T p.Y53= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV99803186; called by muse, mutect2, varscan2
- CDKN2C | c.309G>C p.G103= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99396052; called by muse, mutect2
- DYM | c.441T>A p.L147= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99494144, COSV99494165; called by muse, mutect2, varscan2
- ELOVL6 | c.291A>C p.S97= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs376849709; called by muse, mutect2, varscan2
- EPHB6 | c.1515C>T p.I505= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs1356406588, COSV63893195; called by muse, mutect2, varscan2
- FCRLA | c.48C>T p.V16= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99376619; called by muse, mutect2, varscan2
- GH2 | c.192G>A p.K64= | Silent (SNP) | VAF 114/197 reads (58%) | catalogued as COSV100237136; called by muse, mutect2, varscan2
- GSG1 | c.183C>T p.P61= (on ENST00000651961 / NM_001080555.4; = p.P48= on NM_031289.5) | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100189525; called by muse, mutect2, varscan2
- HDHD3 | c.30G>A p.L10= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1564354885, COSV99445120; called by muse, mutect2, varscan2
- HEXIM2 | c.387A>G p.E129= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100217965; called by muse, mutect2, varscan2
- HLA-G | c.450G>T p.L150= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV100827192; called by muse, mutect2, varscan2
- HSD17B6 | c.18G>A p.A6= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs529002460, COSV100444355; called by muse, mutect2, varscan2
- ITGA1 | c.1353C>G p.L451= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs1561243700, COSV99252134; called by muse, mutect2, varscan2
- LCE2A | c.255C>T p.P85= | Silent (SNP) | VAF 129/212 reads (61%) | catalogued as rs372077582, COSV100909214; called by muse, mutect2, varscan2
- LMBRD1 | c.1527C>T p.F509= (on ENST00000649011; = p.F487= on NM_018368.4) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100992705; called by muse, mutect2, varscan2
- LRP11 | c.723C>T p.V241= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV53335005, COSV99497941; called by muse, mutect2, varscan2
- MAST4 | c.4353G>A p.S1451= (on ENST00000403625 / NM_001164664.2; = p.S1262= on NM_015183.3) | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55115452; called by muse, mutect2, varscan2
- NIPA2 | c.925C>T p.L309= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs759024338, COSV100488774; called by muse, mutect2, varscan2
- NMS | c.384G>A p.A128= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs532961780, COSV65258416, COSV65258515; called by muse, mutect2, varscan2
- PCLO | c.12006T>C p.L4002= | Silent (SNP) | VAF 149/338 reads (44%) | catalogued as COSV100437650; called by muse, mutect2, varscan2
- PNPLA6 | c.2799C>T p.H933= (on ENST00000414982 / NM_001166111.2; = p.H885= on NM_006702.5) | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs886664013, COSV99654491; called by muse, mutect2, varscan2
- PRAMEF17 | c.316C>A p.R106= | Silent (SNP) | VAF 134/380 reads (35%) | catalogued as rs769537184, COSV101068724; called by muse, varscan2
- PRNP | c.381C>A p.G127= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV101057384; called by muse, mutect2, varscan2
- RPL10A | c.93G>T p.T31= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100003587, COSV57689714; called by muse, mutect2, varscan2
- SAMD9L | c.3903G>A p.R1301= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs1232762956, COSV100560782; called by muse, mutect2, varscan2
- STAB2 | c.2256A>G p.G752= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV101186296; called by muse, varscan2
- STEAP2 | c.276T>C p.A92= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV99840692; called by muse, mutect2, varscan2
- TCHH | c.312C>T p.D104= | Silent (SNP) | VAF 137/238 reads (58%) | catalogued as COSV64274729; called by muse, mutect2, varscan2
- TNN | c.3123T>G p.L1041= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99512970; called by muse, mutect2, varscan2
- TRIM32 | c.1740C>T p.G580= | Silent (SNP) | VAF 52/81 reads (64%) | catalogued as rs1435093218, COSV100530263; called by muse, mutect2, varscan2
- WIF1 | c.570C>G p.G190= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99682904, COSV99683420; called by muse, mutect2, varscan2
- ZBTB2 | c.69G>A p.L23= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100287842; called by muse, mutect2, varscan2
- GPHN | c.729+1301G>A | Intron (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100017665; called by muse, mutect2, varscan2
- RPL5 | c.794+158G>A | Intron (SNP) | VAF 12/73 reads (16%) | catalogued as rs777955435, COSV100240494; called by muse, mutect2, varscan2
